Somatic mutation profile of tumor specimen TCGA-V1-A8MJ-01A (aliquot TCGA-V1-A8MJ-01A-11D-A364-08) from TCGA case TCGA-V1-A8MJ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8MJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed9d8085-a44d-4031-9eb7-5a2d219c3d67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8MJ-10A (Blood Derived Normal), aliquot TCGA-V1-A8MJ-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8c1119c-dcaf-43a1-bd77-842017134f33

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as rs587782596, CM920672, COSV52689134, COSV53283559, COSV53738947; ClinVar: pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- C4orf19 | c.234G>C p.W78C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as COSV99448568; called by muse, mutect2, varscan2
- CECR2 | c.1912A>G p.T638A (on ENST00000342247 / NM_001290047.2; = p.T455A on NM_001290046.1) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52845442; called by muse, mutect2, varscan2
- CHRNA2 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs1272630129; called by muse, mutect2
- EMCN | c.458C>G p.T153R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV99598360; called by muse, mutect2, varscan2
- HSPG2 | c.8588G>A p.R2863H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs766365201, COSV65974969; called by muse, mutect2, varscan2
- MUC16 | c.27630A>G p.I9210M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.437); catalogued as COSV101199975; called by muse, mutect2
- NLRP12 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs200736514, COSV60743990, COSV60753353; called by muse, mutect2, varscan2
- OR5M1 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV101591557; called by muse, mutect2
- OR8H2 | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV57943115; called by muse, mutect2, varscan2
- RPH3A | c.651C>A p.G217= (on ENST00000389385 / NM_001143854.2; = p.G213= on NM_014954.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as rs779668181, COSV101231821; called by muse, mutect2, varscan2
- SLC47A1 | c.309G>A p.T103= | Splice Region (SNP) | VAF 5/34 reads (15%) | catalogued as rs202097418, COSV99565329; called by mutect2, varscan2
- SP3 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100021912; called by muse, mutect2, varscan2
- FAT4 | c.13464G>C p.G4488= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100628440, COSV100628638, COSV58702315; called by muse, mutect2, varscan2
- SLC30A8 | c.423C>T p.I141= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV101438488; called by muse, mutect2, varscan2
- TTN | c.94017G>A p.L31339= (on ENST00000591111; = p.L23915= on NM_003319.4) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs371041107; called by muse, mutect2, varscan2
